Somatic mutation profile of tumor specimen MMRF_1782_1_BM_CD138pos (aliquot MMRF_1782_1_BM_CD138pos_T1_KBS5U_K11341) from MMRF case MMRF_1782, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.0 years (23,374 days).
Specimen MMRF_1782_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0c0c175-454c-4814-a86b-6a1e457e1457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1782_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1782_1_PB_Whole_C2_KBS5U_K11342; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9901c419-14ef-45be-a5c3-375cade69b4d

The open-access MAF lists 223 somatic variants for this specimen: 86 protein-altering or splice-affecting, 23 silent, 114 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, 3'UTR 57, Intron 27, Silent 23, 5'UTR 9, 3'Flank 8, RNA 8, 5'Flank 5, Splice Site 4, Frame Shift Del 2, Splice Region 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 52/118 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCA13 | c.7466G>A p.S2489N | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as COSV71285916; called by muse, mutect2, varscan2
- AC011455.2 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs760416819; called by muse, mutect2, varscan2
- CARD10 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1490143209, COSV52658765; called by muse, mutect2
- CDH8 | c.1853G>C p.G618A | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV100183712, COSV54864389; called by muse, mutect2, varscan2
- COG7 | c.644A>T p.D215V | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV56150056; called by muse, mutect2, varscan2
- EGR3 | c.648C>G p.D216E | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.085); catalogued as COSV57834533; called by muse, mutect2
- GLYATL2 | c.727T>A p.Y243N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54849592; called by muse, mutect2, varscan2
- H2AC12 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.954); catalogued as rs780737203, COSV63617075; called by muse, mutect2, varscan2
- IGLV3-25 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs368130042; called by muse, varscan2
- KALRN | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV53780175; called by muse, mutect2, varscan2
- KLHL29 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1042988239; called by muse, mutect2, varscan2
- MAX | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, varscan2
- MCL1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 129/243 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs767724723; called by muse, mutect2, varscan2
- NOS1 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055403935, COSV57606184; called by muse, mutect2
- PABPC3 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 72/74 reads (97%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769964946; called by muse, varscan2
- PRSS37 | c.176del p.P59Qfs*3 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as COSV63339463; called by mutect2, pindel, varscan2
- RASGRF1 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV69176471; called by muse, mutect2, varscan2
- RORB | c.684G>T p.Q228H (on ENST00000396204 / NM_001365023.1; = p.Q217H on NM_006914.4) | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65339502; called by muse, mutect2
- SHROOM3 | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as rs754181595; called by muse, mutect2, varscan2
- SLC24A2 | c.1478C>G p.P493R | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV99647146; called by muse, mutect2
- TRGV3 | c.66G>C p.L22F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as rs369334870; called by muse, mutect2, varscan2
- TTI1 | c.3036G>C p.L1012F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV100989593; called by muse, mutect2, varscan2
- VGLL3 | c.956A>T p.K319M | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375611445; called by muse, mutect2
- ABCC2 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- ACTL7B | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAT3 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- ADGRB3 | c.3405del p.F1135Lfs*9 | Frame Shift Del (DEL) | VAF 64/153 reads (42%) | called by mutect2, pindel, varscan2
- ALOX12 | c.201G>C p.K67N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALOX5 | c.776C>G p.T259S | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARID4A | c.3177_3211+5del p.X1059_splice | Splice Site (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel
- ATP1B4 | c.622A>T p.I208F (on ENST00000218008 / NM_001142447.3; = p.I204F on NM_012069.5) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.025); called by muse, mutect2
- C1orf167 | c.1547G>A p.C516Y | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.03); called by muse, mutect2
- CDK5RAP2 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- CLTC | c.3435T>A p.N1145K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CSMD1 | c.5257A>G p.R1753G (on ENST00000520002; = p.R1752G on NM_033225.6) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DAPK1 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIS3 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DNAH5 | c.10436C>A p.A3479E | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ELP1 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ENO1 | c.1067+2T>A p.X356_splice | Splice Site (SNP) | VAF 33/199 reads (17%) | called by muse, mutect2, varscan2
- EPHA5 | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EPX | c.1981dup p.R661Kfs*17 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | called by mutect2, pindel
- GGNBP2 | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUCY2F | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HSPA6 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HSPG2 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ICE1 | c.3835G>A p.G1279S | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IGLV7-46 | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNK13 | c.964C>G p.R322G | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KMT2E | c.3754T>G p.W1252G | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- LAMB3 | c.737T>G p.L246R | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MAX | c.296-3T>G | Splice Region (SNP) | VAF 19/96 reads (20%) | called by muse, varscan2
- MAX | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYADM | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 32/363 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2
- NNMT | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, varscan2
- NT5DC3 | c.1073A>C p.K358T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.099); called by muse, mutect2
- NUP205 | c.5353A>G p.S1785G | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- OR5A2 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, varscan2
- OR5A2 | c.53T>A p.L18H | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, varscan2
- PCDH15 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLPP3 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PTPN6 | c.747+2T>C p.X249_splice | Splice Site (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2
- RGS7BP | c.485C>G p.T162S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.017); called by muse, mutect2
- ROCK1 | c.1212-1_1221del p.X404_splice | Splice Site (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- RORB | c.685A>C p.N229H (on ENST00000396204 / NM_001365023.1; = p.N218H on NM_006914.4) | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- SASH3 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- SCRN2 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC10A5 | c.577T>G p.F193V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLIT2 | c.3037T>C p.C1013R | Missense Mutation (SNP) | VAF 139/269 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRKH | c.855G>C p.Q285H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM2 | c.6221A>G p.K2074R (on ENST00000518659 / NM_001122679.2; = p.K1835R on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- TMPRSS6 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- TRPA1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UPF2 | c.3616C>A p.Q1206K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- USP34 | c.5710T>C p.Y1904H | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13A | c.7452G>C p.K2484N | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.51); called by muse, mutect2
- VWDE | c.2538T>G p.D846E | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR18 | c.1276T>A p.F426I | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YBX2 | c.272-7C>T | Splice Region (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- ZDBF2 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ZNF254 | c.1970T>C p.L657S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF416 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ZNF548 | c.772T>C p.C258R | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF641 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ZYX | c.1234T>A p.C412S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANAPC1 | c.4725C>T p.S1575= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- CELSR2 | c.3684C>T p.D1228= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs775455786, COSV54767615; called by muse, mutect2, varscan2
- DDX20 | c.741C>T p.P247= | Silent (SNP) | VAF 38/280 reads (14%) | catalogued as rs770298635; called by muse, mutect2, varscan2
- DNAJC22 | c.9G>A p.K3= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- DRD5 | c.1203C>T p.V401= | Silent (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
- GJB7 | c.366C>T p.Y122= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as rs760085047; called by muse, mutect2, varscan2
- HTN3 | c.144G>A p.L48= | Silent (SNP) | VAF 34/315 reads (11%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.255C>T p.G85= | Silent (SNP) | VAF 85/191 reads (45%) | catalogued as rs574148108; called by muse, mutect2, varscan2
- KLF4 | c.285G>A p.E95= | Silent (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- MELK | c.105G>A p.E35= | Silent (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- NID1 | c.1026C>G p.P342= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV51626814; called by muse, mutect2, varscan2
- OR2T2 | c.453T>A p.V151= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2, varscan2
- OR2T8 | c.48T>C p.F16= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- OR5A2 | c.54T>C p.L18= | Silent (SNP) | VAF 76/268 reads (28%) | catalogued as rs764200559; called by muse, varscan2
- PNRC1 | c.165C>A p.L55= | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- PRAG1 | c.288T>C p.S96= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2
- PUM1 | c.1326A>T p.T442= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2
- RRNAD1 | c.285G>A p.A95= | Silent (SNP) | VAF 38/273 reads (14%) | catalogued as rs548109086, COSV57461228; called by muse, mutect2, varscan2
- SARS1 | c.1071T>A p.I357= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- STOX1 | c.2193C>T p.A731= | Silent (SNP) | VAF 33/274 reads (12%) | called by muse, mutect2, varscan2
- SYNJ2 | c.3684C>T p.P1228= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- VWA2 | c.1620C>T p.A540= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs1480948100; called by muse, mutect2, varscan2
- ZNF473 | c.1038C>T p.R346= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- ABCD1 | c.-225G>A | 5'UTR (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- AC124067.4 | n.34T>A | RNA (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- AC136604.1 | n.544A>G | RNA (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- ADARB1 | c.*2298G>C | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- AGGF1 | c.*1787C>G | 3'UTR (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- AIG1 | chr6:143339789 C>G | 3'Flank (SNP) | VAF 57/171 reads (33%) | called by muse, mutect2, varscan2
- AMER3 | c.*1310C>G | 3'UTR (SNP) | VAF 15/185 reads (8%) | called by muse, mutect2
- ANHX | c.*290G>A | 3'UTR (SNP) | VAF 14/178 reads (8%) | catalogued as rs989248337; called by muse, mutect2
- ANO1 | c.109-2176G>A | Intron (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503841 del ATA | 5'Flank (DEL) | VAF 83/250 reads (33%) | catalogued as rs747696623; called by pindel, varscan2
- ARSJ | c.-389A>G | 5'UTR (SNP) | VAF 21/212 reads (10%) | called by muse, mutect2, varscan2
- ATG7 | c.2080-44547_2080-44538delinsA | Intron (DEL) | VAF 53/188 reads (28%) | called by pindel, varscan2*
- BMP8B | c.*402G>C | 3'UTR (SNP) | VAF 23/110 reads (21%) | catalogued as rs1274111600; called by muse, mutect2, varscan2
- C10orf53 | c.*1326G>A | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96090519 C>A | 3'Flank (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- C1orf109 | c.*669G>C | 3'UTR (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- C5orf60 | n.1034G>A | RNA (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2
- CCL3 | c.-80G>A | 5'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs957825194; called by muse, mutect2, varscan2
- CFAP77 | c.*755C>G | 3'UTR (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- CHI3L2 | c.*199A>G | 3'UTR (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- CHRDL1 | c.*1346G>T | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- CKMT1A | c.876+72A>T | Intron (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- CMTM7 | c.*914G>A | 3'UTR (SNP) | VAF 14/88 reads (16%) | catalogued as rs984645817; called by muse, mutect2, varscan2
- CNP | c.*3557G>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- CSMD1 | chr8:2935810 T>A | 3'Flank (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- CYB561D1 | c.*1614C>A | 3'UTR (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- DCP2 | c.*2699T>A | 3'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- DIDO1 | c.*49C>T | 3'UTR (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- DUS2 | c.264+11C>G | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- DUSP6 | chr12:89352876 G>C | 5'Flank (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- DZIP1 | c.*3295C>T | 3'UTR (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- ELMOD2 | c.*2266C>A | 3'UTR (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- EPC1 | c.1933-41T>A | Intron (SNP) | VAF 7/66 reads (11%) | called by muse, varscan2
- FAM114A2 | c.*1069T>A | 3'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- FAM166C | c.462-402A>T | Intron (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- FAM71F2 | c.*92G>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1431597297; called by muse, mutect2
- GABRG1 | c.*1389A>T | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- GALNT10 | c.*3215G>A | 3'UTR (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- GIMAP1 | c.*3228G>C | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- GNPTAB | c.*687G>T | 3'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- GORAB | c.662+795A>T | Intron (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- GREM1 | c.*2206T>A | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- H1-10 | c.*124G>A | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- H2AJ | c.-33C>T | 5'UTR (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- HACD4 | c.*320T>G | 3'UTR (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- HELLPAR | n.200469G>C | RNA (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- HOXA3 | c.*873A>G | 3'UTR (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- HYDIN2 | n.8794G>T | RNA (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.711+76C>T | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2
- KCND1 | c.1122-528C>G | Intron (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- KCNE4 | c.*1001C>T | 3'UTR (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*1583T>C | 3'UTR (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2
- KLHL20 | c.*78A>G | 3'UTR (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- KLHL29 | c.940+356T>C | Intron (SNP) | VAF 5/34 reads (15%) | called by muse, varscan2
- LASP1 | c.*2076C>T | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- LINC01621 | n.410C>G | RNA (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- LIPC | c.1389-2490G>A | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- LMAN1 | c.*2172G>C | 3'UTR (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- LMBRD2 | c.175-30C>T | Intron (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- MAP3K20 | c.987+4967A>C | Intron (SNP) | VAF 14/55 reads (25%) | called by mutect2, varscan2
- MATN1 | c.*872G>A | 3'UTR (SNP) | VAF 68/152 reads (45%) | catalogued as rs527566256; called by mutect2, varscan2
- MICAL3 | c.2802-2381C>T | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- MICALL2 | c.1805+74G>T | Intron (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- MIR1915 | chr10:21496830 T>A | 5'Flank (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- MIR34A | chr1:9151584 C>T | 3'Flank (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- MKRN1 | c.*1275G>A | 3'UTR (SNP) | VAF 126/368 reads (34%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+4163A>C | Intron (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- MYEOV | c.*320A>G | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- MYO1A | c.*172A>G | 3'UTR (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- NCEH1 | c.*501G>A | 3'UTR (SNP) | VAF 12/151 reads (8%) | called by muse, mutect2
- NEK6 | c.*796G>A | 3'UTR (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- NFATC2IP | c.*1067C>T | 3'UTR (SNP) | VAF 12/78 reads (15%) | called by mutect2, varscan2
- NFIB | c.*5663A>C | 3'UTR (SNP) | VAF 9/44 reads (20%) | catalogued as rs1472180771; called by muse, mutect2, varscan2
- NIPSNAP2 | c.278+32A>G | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2
- NUDT16 | c.409-354G>A | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- OR52A1 | c.-90A>T | 5'UTR (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- PATJ | c.4655+47C>T | Intron (SNP) | VAF 36/396 reads (9%) | catalogued as rs1251799172; called by muse, mutect2
- PDXDC1 | chr16:14974847 C>A | 5'Flank (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- PICALM | c.*143G>A | 3'UTR (SNP) | VAF 16/311 reads (5%) | called by muse, mutect2
- PLA2G6 | c.1349-889A>T | Intron (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- POU2AF1 | c.-8A>T | 5'UTR (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- PPM1A | c.953-1326T>G | Intron (SNP) | VAF 5/30 reads (17%) | called by mutect2, varscan2
- PSMG3-AS1 | n.3873C>T | RNA (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- RALGPS1 | c.*408C>T | 3'UTR (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- RASGRF2 | c.*126C>A | 3'UTR (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- RBFOX1 | c.28-185342G>A | Intron (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- RBFOX3 | c.569-116G>A | Intron (SNP) | VAF 16/99 reads (16%) | catalogued as rs1291810252; called by muse, mutect2, varscan2
- RBM33 | c.*655C>T | 3'UTR (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- RMDN3 | c.-970dup | 5'UTR (INS) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- RNF217-AS1 | n.2692C>T | RNA (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- ROR1 | c.1174+722_1174+735del | Intron (DEL) | VAF 26/87 reads (30%) | called by mutect2, varscan2
- SETX | c.*1927T>C | 3'UTR (SNP) | VAF 53/93 reads (57%) | called by muse, mutect2, varscan2
- SFMBT2 | c.*3179C>T | 3'UTR (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- SGMS2 | chr4:107913359 T>C | 3'Flank (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- SQLE | c.-210C>T | 5'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- SREK1 | chr5:66183505 T>C | 3'Flank (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- THAP5 | c.-84G>T | 5'UTR (SNP) | VAF 33/100 reads (33%) | catalogued as COSV99974433; called by muse, mutect2, varscan2
- TMED3 | c.*298G>T | 3'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- TMEM86B | c.51+34G>T | Intron (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- TNKS2 | c.*94T>A | 3'UTR (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- TRPV3 | c.*1747G>C | 3'UTR (SNP) | VAF 43/71 reads (61%) | called by muse, mutect2, varscan2
- TUBB3 | c.278-506G>A | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- U2SURP | c.*2352A>G | 3'UTR (SNP) | VAF 33/87 reads (38%) | catalogued as rs968094038; called by muse, mutect2, varscan2
- UBE2NL | c.*55C>G | 3'UTR (SNP) | VAF 109/304 reads (36%) | called by muse, mutect2, varscan2
- UROC1 | c.*893G>C | 3'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs886965243; called by muse, mutect2, varscan2
- UST | c.*165T>C | 3'UTR (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- WASF3 | c.*592C>G | 3'UTR (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
- WIPF1 | chr2:174560693 G>A | 3'Flank (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- YPEL5 | c.*220G>T | 3'UTR (SNP) | VAF 8/117 reads (7%) | catalogued as COSV99745386; called by muse, mutect2
- ZBTB11 | chr3:101677389 C>T | 5'Flank (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ZBTB7B | chr1:155016999 G>C | 3'Flank (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- ZC3H11A | c.299-38C>A | Intron (SNP) | VAF 18/201 reads (9%) | called by muse, mutect2
- ZC4H2 | c.*1380T>C | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- ZDHHC22 | c.*586T>C | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
